Somatic mutation profile of tumor specimen MMRF_1523_1_BM_CD138pos (aliquot MMRF_1523_1_BM_CD138pos_T1_KBS5U_L05074) from MMRF case MMRF_1523, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.5 years (21,726 days).
Specimen MMRF_1523_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 347054c6-67d0-446c-b7f2-9440d5dc591a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1523_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1523_1_PB_Whole_C2_KBS5U_L05082; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1cd38a-c3be-4982-a546-dd54e019e004

The open-access MAF lists 78 somatic variants for this specimen: 28 protein-altering or splice-affecting, 14 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 20, Silent 14, Intron 7, 5'UTR 4, RNA 4, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 2, Splice Region 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 71/149 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 189/435 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.7075G>A p.A2359T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs1359657635; called by muse, mutect2, varscan2
- IGHV2-70 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.453); catalogued as rs373474286; called by muse, varscan2
- KIF26A | c.5026G>A p.A1676T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs368723517; called by muse, mutect2, varscan2
- OR4F6 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.392); catalogued as COSV61026593; called by muse, mutect2
- PLXNA1 | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266858113, COSV52522521; called by muse, mutect2, varscan2
- PP2D1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV56084296; called by muse, mutect2
- RTP1 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1478799824; called by muse, mutect2
- SERPINB8 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 163/344 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as rs150328649, COSV54639280; called by muse, mutect2, varscan2
- SHANK3 | c.3631G>A p.G1211R | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754607187; called by muse, mutect2, varscan2
- TDRD15 | c.1854del p.K618Nfs*2 | Frame Shift Del (DEL) | VAF 27/56 reads (48%) | catalogued as COSV68267207; called by mutect2, pindel, varscan2
- BBS9 | c.86A>T p.N29I | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- CCDC39 | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CR1 | c.5020G>T p.E1674* | Nonsense Mutation (SNP) | VAF 34/139 reads (24%) | called by muse, mutect2, varscan2
- CRIM1 | c.263T>G p.L88R | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DLEC1 | c.2993T>C p.L998P | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ERVMER34-1 | c.522_523insC p.T175Hfs*8 | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- FOXJ3 | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- H1-4 | c.486_488dup p.A165dup | In Frame Ins (INS) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- IGLV2-23 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.071); called by muse, varscan2
- KDM6A | c.1376del p.P459Qfs*11 | Frame Shift Del (DEL) | VAF 43/61 reads (70%) | called by mutect2, pindel, varscan2
- MRPL53 | c.257_258insTCTCACCGCTCTG p.M86Ifs*28 | Frame Shift Ins (INS) | VAF 48/102 reads (47%) | called by mutect2, varscan2*
- NRXN1 | c.3437G>C p.S1146T | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PDGFRA | c.3110G>T p.R1037M | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS7BP | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A7 | c.1124-5C>A | Splice Region (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- ZFAT | c.3706G>A p.V1236M | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD18A | c.2451T>G p.G817= | Silent (SNP) | VAF 9/12 reads (75%) | called by muse, varscan2
- GRIN2D | c.2301C>T p.A767= | Silent (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as rs367953381; called by muse, varscan2
- IGLV2-23 | c.340G>C p.*114= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs528587410; called by muse, mutect2, varscan2
- IL32 | c.318T>A p.A106= (on ENST00000396890 / NM_001308078.4; = p.A60= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- MRTFA | c.1521G>A p.V507= | Silent (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- NEXMIF | c.3201C>T p.S1067= | Silent (SNP) | VAF 50/50 reads (100%) | catalogued as COSV50066752, COSV50113835; called by muse, mutect2, varscan2
- OBSCN | c.13530C>T p.D4510= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs1469709345; called by muse, mutect2, varscan2
- PPP1R9B | c.1287G>T p.S429= | Silent (SNP) | VAF 75/197 reads (38%) | called by muse, mutect2, varscan2
- PSPC1 | c.720T>C p.D240= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs932918218; called by muse, mutect2, varscan2
- RYR2 | c.13800T>C p.F4600= | Silent (SNP) | VAF 81/258 reads (31%) | called by muse, mutect2
- SPECC1 | c.1269G>A p.E423= | Silent (SNP) | VAF 81/197 reads (41%) | called by muse, mutect2, varscan2
- TNS1 | c.4206C>G p.P1402= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- TOPBP1 | c.3207G>A p.E1069= | Silent (SNP) | VAF 82/175 reads (47%) | catalogued as rs1321702452, COSV99605052; called by muse, mutect2, varscan2
- AC073316.1 | n.301C>T | RNA (SNP) | VAF 111/221 reads (50%) | catalogued as rs148687951; called by muse, mutect2, varscan2
- ACACA | c.*386T>C | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- AL589674.1 | n.218G>A | RNA (SNP) | VAF 21/45 reads (47%) | catalogued as rs999205655; called by mutect2, varscan2
- AP005242.2 | n.979G>A | RNA (SNP) | VAF 33/68 reads (49%) | catalogued as rs918174913; called by muse, mutect2, varscan2
- ASPSCR1 | c.1405+80G>A | Intron (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- AZIN1 | c.*254T>C | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- CACNG8 | c.*950C>T | 3'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as rs7257865; called by muse, mutect2, varscan2
- CAMK4 | c.*4125A>T | 3'UTR (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- CDH19 | c.*897G>A | 3'UTR (SNP) | VAF 21/91 reads (23%) | catalogued as rs1045631394; called by muse, mutect2, varscan2
- DEPDC1 | c.*2492G>A | 3'UTR (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- FMN1 | c.2161+1995C>A | Intron (SNP) | VAF 88/166 reads (53%) | catalogued as COSV57935607; called by muse, mutect2, varscan2
- GABRG1 | c.*4239T>C | 3'UTR (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- GATA5 | c.*589G>A | 3'UTR (SNP) | VAF 79/200 reads (40%) | catalogued as rs988242118; called by muse, mutect2
- GNA14 | c.-425T>A | 5'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- HHIP | c.*417A>T | 3'UTR (SNP) | VAF 46/76 reads (61%) | catalogued as rs202086153, COSV99667925; called by muse, mutect2, varscan2
- KRT6A | c.-53C>G | 5'UTR (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100417202; called by muse, mutect2, varscan2
- KRTAP19-7 | c.*71G>A | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- LINC00544 | n.742G>A | RNA (SNP) | VAF 53/106 reads (50%) | catalogued as rs1234190999; called by muse, mutect2, varscan2
- MARCHF4 | c.-782C>T | 5'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- MSX1 | c.*333T>C | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- NACC2 | c.*966G>A | 3'UTR (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- NCKAP5 | c.341+7928T>G | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- NFKBIA | c.228-118C>T | Intron (SNP) | VAF 48/81 reads (59%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54575971 G>A | 3'Flank (SNP) | VAF 33/83 reads (40%) | catalogued as rs959385361; called by muse, mutect2, varscan2
- PRR5L | c.*372A>G | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- RGS10 | c.-80T>C | 5'UTR (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- RIF1 | c.*281delinsCC | 3'UTR (INS) | VAF 35/97 reads (36%) | called by pindel, varscan2*
- RYR2 | c.11146-1224G>A | Intron (SNP) | VAF 28/345 reads (8%) | catalogued as rs976921528; called by muse, mutect2
- SLC20A2 | c.*170G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as rs756318278; called by muse, mutect2, varscan2
- SLC7A2 | c.*4724C>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SLC9C2 | c.*581T>C | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- SP140 | c.2361+96G>C | Intron (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- TBC1D15 | c.*3716C>T | 3'UTR (SNP) | VAF 16/28 reads (57%) | catalogued as rs1036073391; called by muse, mutect2, varscan2
- TNS1 | c.212-28T>G | Intron (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- TSEN34 | c.*103G>A | 3'UTR (SNP) | VAF 9/195 reads (5%) | catalogued as rs1446186140; called by muse, mutect2
- ZNF480 | c.*328C>T | 3'UTR (SNP) | VAF 41/102 reads (40%) | catalogued as rs903298122; called by muse, mutect2, varscan2
